MMRF case MMRF_2236 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d3abb537-dc9e-4263-98c6-ce12b119fd85

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.1 years (21,229 days); ISS stage: II; Days to last known disease status: 868 days (2.4 years); Days to last follow up: 868 days (2.4 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 868.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.46 mg/dL; Immunoglobulin G 34.9 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 39.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 27 g/L; Total Protein 9.1 g/dL; Glucose 4.73 mmol/L; C-Reactive Protein 0.463 mg/dL.
- Day 92 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 8.64 mmol/L.
- Day 183 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 6.95 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 355 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 7.26 mmol/L.
- Day 288 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.82 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.83 mmol/L.
- Day 372 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.95 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 301 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 3.8 mmol/L.
- Day 625 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.5 mmol/L.
- Day 757 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.35 mg/dL; Immunoglobulin G 23.6 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 291 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 8.5 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -12: Weight: 65 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2236_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_2236_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
